Gene-level copy-number profile of tumor specimen TCGA-RD-A7BW-01A from TCGA case TCGA-RD-A7BW, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 68.5 years (25,036 days).
Specimen TCGA-RD-A7BW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.2a0c31b1-50a8-45a7-b5d9-ff952abbe4a6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RD-A7BW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5f0602e3-c5d2-4cd9-8bc1-2a71bb01c63c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,730; copy number 2: 48,911; copy number 3: 2,337; copy number 4: 805; copy number 5: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-RD-A7BW-01): tumor purity 0.18, ploidy 1.88, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 32 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:29,287,011–30,016,612, 16 genes, copy number 5 (within-gene range 1–5): AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32.
- chr19:32,405,543–32,869,767, 16 genes, copy number 5 (within-gene range 3–5): DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22.

Autosomal genes at a single copy (total copy number 1): 7,730. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
